Somatic mutation profile of tumor specimen 0DR0CS from CCDI case PBCFXX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Colon, NOS; Age at diagnosis: 16.1 years (5,881 days).
Specimen 0DR0CS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad24abcd-4ad7-4df6-b9f4-d270ade62def.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR0CE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32c12812-790c-4cb3-8737-4c9cbdafc2c3

The open-access MAF lists 26,046 somatic variants for this specimen: 16,017 protein-altering or splice-affecting, 5,579 silent, 4,450 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14,665, Silent 5,579, Intron 2,603, 3'UTR 1,008, 5'UTR 533, Nonsense Mutation 529, Splice Region 286, Splice Site 278, Frame Shift Ins 156, RNA 124, 5'Flank 117, Frame Shift Del 75.

Variants (750 of 26,046; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.3662G>A p.R1221H | Missense Mutation (SNP) | VAF 59/363 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs63751001, CM065962; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACADS | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 47/409 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374726386, CM067633; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD11 | c.3562C>T p.R1188* | Nonsense Mutation (SNP) | VAF 179/968 reads (18%) | catalogued as rs761848111, COSV56360846; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKRD11 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 130/726 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746852311; ClinVar: likely pathogenic; called by muse, varscan2
- ARL13B | c.599G>A p.R200H (on ENST00000394222 / NM_001174150.2; = p.R93H on NM_144996.4) | Missense Mutation (SNP) | VAF 249/1529 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764109067; ClinVar: likely pathogenic; called by muse, varscan2
- ATM | c.8287C>T p.R2763* | Nonsense Mutation (SNP) | VAF 180/829 reads (22%) | catalogued as rs876659872, CM080077, COSV53734668; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AUTS2 | c.1974G>A p.W658* | Nonsense Mutation (SNP) | VAF 232/846 reads (27%) | catalogued as rs886041609; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BMPR1B | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 185/1270 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as rs745854387, CM156116; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CA4 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 140/789 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs121434552, CM072913, COSV56282434, COSV99039723; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CAPN3 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 83/670 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs863224956, CM129344, CM990311, COSV58826312; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CFAP20 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 95/575 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs753911484, COSV52630441; called by muse, varscan2
- COL11A2 | c.966dup p.T323Hfs*19 | Frame Shift Ins (INS) | VAF 66/524 reads (13%) | catalogued as rs748440351; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- CTCF | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 103/556 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50461516; called by muse, mutect2, varscan2
- CTLA4 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 136/633 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553657387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DCX | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 161/899 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587783541, CM131051, CM980524, COSV57565978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH11 | c.4438C>T p.R1480* | Nonsense Mutation (SNP) | VAF 324/1368 reads (24%) | catalogued as rs72657321, CM1110333; ClinVar: pathogenic; called by muse, varscan2
- DNMT3A | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 109/617 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs1553414070, COSV53046262; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- DUSP16 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 134/679 reads (20%) | hotspot (GDC flag); catalogued as COSV53806110; called by muse, mutect2, varscan2
- EARS2 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 50/266 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs749912939, CM147827; ClinVar: likely pathogenic; called by muse, varscan2
- EPCAM | c.491+1G>A p.X164_splice | Splice Site (SNP) | VAF 105/923 reads (11%) | catalogued as rs606231203, CS083989, COSV55392567; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 130/738 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- EZH2 | c.2172dup p.D725* (on ENST00000460911 / NM_001203247.2; = p.D730* on NM_004456.5) | Frame Shift Ins (INS) | VAF 282/1650 reads (17%) | catalogued as rs797045568; ClinVar: pathogenic; called by pindel, varscan2
- FAM20C | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 129/491 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730882220, CM150868, COSV58237435; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXL3 | c.884del p.L295Yfs*25 | Frame Shift Del (DEL) | VAF 102/577 reads (18%) | catalogued as rs764008859; ClinVar: pathogenic; called by mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 192/1243 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, varscan2
- FH | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 205/1240 reads (17%) | catalogued as rs121913120, CD1511505, CM020700; ClinVar: pathogenic; called by muse, varscan2
- GAA | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 66/402 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs528367092, CM082741; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GJB1 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 89/607 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs116840819, CM970660; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- GLB1 | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 202/1039 reads (19%) | catalogued as rs72555359, CM910188, COSV56568786; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLDC | c.2527C>T p.R843* | Nonsense Mutation (SNP) | VAF 70/543 reads (13%) | catalogued as rs1554643360, CM1510049, COSV58684075; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IDH2 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 80/414 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs767061831; ClinVar: likely pathogenic; called by muse, varscan2
- IL2RG | c.980A>G p.E327G | Missense Mutation (SNP) | VAF 26/608 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1064794631; ClinVar: likely pathogenic; called by muse, mutect2
- INPPL1 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 66/447 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53353022, COSV99995692; called by muse, mutect2, varscan2
- IRAK4 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 267/1211 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377584435, CM078314; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KMT2B | c.7759C>T p.R2587* | Nonsense Mutation (SNP) | VAF 53/333 reads (16%) | catalogued as rs1555734923, COSV53073648; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LAMB2 | c.2890C>T p.R964* | Nonsense Mutation (SNP) | VAF 94/499 reads (19%) | catalogued as rs730880125, CM164970, COSV59731383; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LSM14A | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 106/634 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV70884731; called by muse, mutect2, varscan2
- MED13L | c.5278C>T p.R1760* | Nonsense Mutation (SNP) | VAF 185/1069 reads (17%) | catalogued as rs886041448, COSV99929718; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MEGF8 | c.4697G>A p.R1566H (on ENST00000251268 / NM_001271938.2; = p.R1499H on NM_001410.3) | Missense Mutation (SNP) | VAF 77/388 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs397515427, CM1210238, COSV52083808; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.2647del p.I883Lfs*9 | Frame Shift Del (DEL) | VAF 137/841 reads (16%) | catalogued as rs63750084; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MYH7 | c.2609G>A p.R870H | Missense Mutation (SNP) | VAF 160/802 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs36211715, CM1412215, CM952025, COSV62524343; ClinVar: pathogenic; called by muse, varscan2
- PDE6B | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 107/516 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs201541131, CM155389; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- PHIP | c.3706C>T p.R1236* | Nonsense Mutation (SNP) | VAF 178/1471 reads (12%) | catalogued as rs1554196416, COSV51510015; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PHKA2 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 48/329 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs797044877, CM991038, COSV101177128; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 226/1193 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PKD1 | c.10745dup p.V3584Rfs*43 (on ENST00000262304 / NM_001009944.3; = p.V3583Rfs*43 on NM_000296.4) | Frame Shift Ins (INS) | VAF 55/412 reads (13%) | catalogued as rs1555447011; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PRDM14 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 75/411 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762086448, COSV52571818; called by muse, mutect2, varscan2
- RET | c.2437C>T p.R813W | Missense Mutation (SNP) | VAF 96/597 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779996040; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RNF43 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 211/446 reads (47%) | hotspot (GDC flag); catalogued as rs786205215, CM154177, COSV68457376; ClinVar: pathogenic; called by muse, varscan2
- SCN1A | c.3824G>A p.G1275D (on ENST00000303395 / NM_001202435.3; = p.G1264D on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 283/1459 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs796053000, CM096145, CM136395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.4132G>A p.V1378M (on ENST00000333535 / NM_198056.3; = p.V1377M on NM_000335.5) | Missense Mutation (SNP) | VAF 129/590 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748312802, CM123252; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SETBP1 | c.1873C>T p.R625* | Nonsense Mutation (SNP) | VAF 187/916 reads (20%) | catalogued as rs606231272, CM149062, COSV56321163; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC5A1 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 95/507 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774651252, COSV56683792; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLC9A6 | c.1543G>T p.E515* | Nonsense Mutation (SNP) | VAF 91/1169 reads (8%) | catalogued as rs398123003, CM1312050; ClinVar: pathogenic; called by muse, mutect2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 520/1336 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3127C>T p.R1043W | Missense Mutation (SNP) | VAF 100/531 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770014321, CM1310763, COSV60785646; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMARCB1 | c.992G>A p.R331H (on ENST00000263121; = p.R377H on NM_003073.5) | Missense Mutation (SNP) | VAF 64/518 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs387906812, CM122478, COSV51954090, COSV51954233, COSV51954740; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- SMC1A | c.3197G>A p.R1066H | Missense Mutation (SNP) | VAF 150/879 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1556886034; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMC1A | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 107/540 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs122454123, CM071098; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMPD1 | c.564del p.K189Nfs*68 | Frame Shift Del (DEL) | VAF 47/325 reads (14%) | catalogued as rs756366019; ClinVar: pathogenic; called by mutect2, pindel
- STXBP1 | c.1651C>T p.R551C | Missense Mutation (SNP) | VAF 169/794 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs796053373, CM125342, CM1513639, COSV64813774; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SYNGAP1 | c.1717C>T p.R573W | Missense Mutation (SNP) | VAF 156/796 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064795331, COSV53384814; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TBX19 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 123/724 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs748717639, COSV63197049; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TBX6 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 58/332 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200175825, CM154544, COSV99661396; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGFBI | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 75/1030 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.958); catalogued as rs121909211, CM971472, CM981909, CP05317, COSV59350998; ClinVar: pathogenic; called by muse, mutect2
- THRB | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 152/1060 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918693, CM930704, CM941313; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TOE1 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 114/670 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs371848318; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 105/602 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 90/381 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.154); catalogued as rs587782596, CM920672, COSV52689134, COSV53283559, COSV53738947; ClinVar: pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- TRMT1 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 117/593 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542184779, COSV99679013; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TSHR | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 91/554 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772490052, COSV53315668; ClinVar: likely pathogenic; called by muse, varscan2
- TTN | c.45160C>T p.R15054* (on ENST00000591111; = p.R7630* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 210/1041 reads (20%) | catalogued as rs751502842, COSV100592805, COSV59935923; ClinVar: pathogenic; called by muse, varscan2
- TTPA | c.552G>A p.T184= | Splice Region (SNP) | VAF 151/753 reads (20%) | catalogued as rs181109321, CS971923; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- UGDH | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 129/631 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs749975104, COSV57098638; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ZFYVE26 | c.4804C>T p.R1602* | Nonsense Mutation (SNP) | VAF 133/770 reads (17%) | catalogued as rs558285072; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ZNF462 | c.3202C>T p.R1068* | Nonsense Mutation (SNP) | VAF 141/800 reads (18%) | catalogued as rs562767308, COSV52942682; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1535C>T p.T512M (on ENST00000373993 / NM_138932.2; = p.T504M on NM_014576.4) | Missense Mutation (SNP) | VAF 180/1535 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs1167572371; called by muse, mutect2, varscan2
- A2M | c.3017G>A p.G1006D | Missense Mutation (SNP) | VAF 86/895 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs746166406; called by muse, mutect2, varscan2
- A2ML1 | c.3061G>A p.G1021S | Missense Mutation (SNP) | VAF 174/891 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1565485213; called by muse, mutect2, varscan2
- A3GALT2 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 54/281 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.059); catalogued as rs749253575; called by muse, mutect2, varscan2
- AADACL4 | c.346A>G p.I116V | Missense Mutation (SNP) | VAF 70/667 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.04); catalogued as COSV100879325, COSV66106178; called by muse, mutect2, varscan2
- AADACL4 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 265/656 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.086); catalogued as rs139261871; called by muse, mutect2, varscan2
- AAK1 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 193/997 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs773204637, COSV68641788; called by muse, mutect2, varscan2
- AAMP | c.587G>A p.G196D | Missense Mutation (SNP) | VAF 118/556 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50307241; called by muse, mutect2, varscan2
- AANAT | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 37/282 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.83); catalogued as rs1357558122; called by muse, mutect2, varscan2
- AAR2 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 100/594 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.39); catalogued as rs138947526, COSV57924117; called by muse, varscan2
- AARS2 | c.2861C>T p.A954V | Missense Mutation (SNP) | VAF 134/604 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as rs747312867, COSV55113970; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AASDH | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 176/884 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770958760; called by muse, varscan2
- AATK | c.694C>T p.R232C (on ENST00000326724 / NM_001080395.3; = p.R129C on NM_004920.2) | Missense Mutation (SNP) | VAF 91/451 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1409353722; called by muse, varscan2
- ABCA10 | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 200/1066 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs576357865; called by muse, mutect2, varscan2
- ABCA12 | c.4642G>A p.A1548T (on ENST00000272895 / NM_173076.3; = p.A1230T on NM_015657.3) | Missense Mutation (SNP) | VAF 334/946 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754893598, COSV55974837; called by muse, varscan2
- ABCA13 | c.11152G>A p.A3718T | Missense Mutation (SNP) | VAF 199/914 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777083484, COSV71285284; called by muse, mutect2, varscan2
- ABCA2 | c.6883C>T p.R2295W (on ENST00000614293; = p.R2265W on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 109/523 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs767665301; called by muse, varscan2
- ABCA2 | c.2758G>A p.D920N (on ENST00000614293; = p.D890N on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 109/486 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as rs757517721, COSV99687615; called by muse, varscan2
- ABCA3 | c.2032G>A p.A678T | Missense Mutation (SNP) | VAF 94/512 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs769584477; called by muse, mutect2, varscan2
- ABCA3 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 104/495 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV57054263; called by muse, mutect2, varscan2
- ABCA4 | c.6298G>T p.G2100W | Missense Mutation (SNP) | VAF 183/958 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64674298; called by muse, mutect2, varscan2
- ABCA6 | c.4427C>T p.A1476V | Missense Mutation (SNP) | VAF 249/1415 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as rs760596501; called by muse, mutect2, varscan2
- ABCA6 | c.4249A>G p.I1417V | Missense Mutation (SNP) | VAF 168/1573 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.019); catalogued as rs1189049628, COSV52641938; called by muse, mutect2, varscan2
- ABCA6 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 188/1040 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99445769; called by muse, mutect2, varscan2
- ABCA9 | c.2849G>A p.G950D | Missense Mutation (SNP) | VAF 261/1358 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as COSV60628243; called by muse, mutect2, varscan2
- ABCB11 | c.3083C>T p.A1028V | Missense Mutation (SNP) | VAF 140/1238 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs1171209104, COSV55585715; called by muse, varscan2
- ABCB11 | c.1841C>T p.A614V | Missense Mutation (SNP) | VAF 285/1632 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs1384540976, COSV55599979; called by muse, varscan2
- ABCB4 | c.3692G>A p.R1231H (on ENST00000265723 / NM_018849.3; = p.R1224H on NM_000443.4) | Missense Mutation (SNP) | VAF 169/1087 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs144790968; called by muse, mutect2, varscan2
- ABCB4 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 148/1346 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397514620, CM082462, CM159639; called by muse, mutect2, varscan2
- ABCB5 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 272/1656 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749580728; called by muse, mutect2, varscan2
- ABCB9 | c.1295G>A p.G432D | Missense Mutation (SNP) | VAF 169/824 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749939110, COSV54891394; called by muse, mutect2, varscan2
- ABCC1 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 42/354 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60693100; called by muse, varscan2
- ABCC1 | c.3319G>A p.V1107I | Missense Mutation (SNP) | VAF 100/554 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1367965919, COSV100579569; called by muse, varscan2
- ABCC10 | c.3247C>T p.R1083C (on ENST00000372530 / NM_001198934.2; = p.R1055C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/305 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.567); catalogued as rs41281804; called by muse, mutect2, varscan2
- ABCC12 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 104/821 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as rs543162145, COSV100252768; called by muse, varscan2
- ABCC3 | c.3995T>C p.M1332T | Missense Mutation (SNP) | VAF 78/494 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs866575899; called by muse, varscan2
- ABCC3 | c.4072G>A p.G1358S | Missense Mutation (SNP) | VAF 118/559 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs187814086, COSV53323190; called by muse, varscan2
- ABCC3 | c.4142G>A p.R1381H | Missense Mutation (SNP) | VAF 120/615 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs182137402, COSV53321191; called by muse, mutect2, varscan2
- ABCC4 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 124/712 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs145252193; called by muse, mutect2, varscan2
- ABCC4 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 158/908 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.108); catalogued as rs1400854469, COSV65312418; called by muse, mutect2, varscan2
- ABCC5 | c.3244G>A p.D1082N | Missense Mutation (SNP) | VAF 80/615 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV55592029; called by muse, varscan2
- ABCC6 | c.1160G>A p.G387D | Missense Mutation (SNP) | VAF 73/626 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52746561; called by muse, mutect2, varscan2
- ABCC8 | c.2153G>A p.G718D | Missense Mutation (SNP) | VAF 78/502 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD107113; called by muse, mutect2, varscan2
- ABCC8 | c.1818C>T p.S606= | Splice Region (SNP) | VAF 144/617 reads (23%) | catalogued as rs202207978; called by muse, varscan2
- ABCC8 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 231/1202 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as CM068329, COSV56847018; called by muse, mutect2, varscan2
- ABCC9 | c.2474C>T p.A825V | Missense Mutation (SNP) | VAF 118/1139 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs964127282, COSV53973119; called by muse, mutect2, varscan2
- ABCC9 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 155/929 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs374849789; called by muse, mutect2, varscan2
- ABCD1 | c.1894A>G p.T632A | Missense Mutation (SNP) | VAF 60/262 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM108117; called by muse, mutect2, varscan2
- ABCE1 | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 250/1340 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1190531936, COSV56847756; called by muse, mutect2, varscan2
- ABCF1 | c.1183C>T p.R395W (on ENST00000326195 / NM_001025091.2; = p.R357W on NM_001090.3) | Missense Mutation (SNP) | VAF 156/804 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs989406749, COSV58229226; called by muse, mutect2, varscan2
- ABCF3 | c.1753C>T p.R585W | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs373058650; called by muse, varscan2
- ABCG1 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 110/527 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs777446902; called by muse, mutect2, varscan2
- ABCG2 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 99/728 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1368809743; called by muse, mutect2, varscan2
- ABCG2 | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 88/620 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99419970; called by muse, mutect2, varscan2
- ABCG5 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 98/539 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as rs376129056, COSV53209176; ClinVar: uncertain significance; called by muse, varscan2
- ABCG8 | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 135/758 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99699854; called by muse, mutect2, varscan2
- ABCG8 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 123/663 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs759147053, COSV55396094; called by muse, mutect2, varscan2
- ABHD1 | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 63/583 reads (11%) | catalogued as rs774004040; called by muse, mutect2, varscan2
- ABHD11 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 79/430 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.53); catalogued as rs1554622365, COSV56105903; called by muse, mutect2, varscan2
- ABHD14B | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 54/406 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as rs373286106; called by muse, varscan2
- ABHD17A | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 57/364 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs201739132; called by muse, mutect2, varscan2
- ABHD18 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 155/1001 reads (15%) | catalogued as rs574956758; called by muse, varscan2
- ABHD3 | c.884T>C p.V295A | Missense Mutation (SNP) | VAF 76/667 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.304); catalogued as rs377709120; called by muse, varscan2
- ABHD6 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 132/726 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.025); catalogued as rs764884963, COSV55910261; called by muse, mutect2, varscan2
- ABI3 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 64/516 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761778675, COSV56799705; called by muse, varscan2
- ABI3BP | c.1691C>T p.T564M | Missense Mutation (SNP) | VAF 323/1792 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs377173411; called by muse, mutect2, varscan2
- ABL1 | c.1639G>A p.V547M | Missense Mutation (SNP) | VAF 137/599 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs574660646; called by muse, mutect2, varscan2
- ABLIM1 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 138/811 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV53315821; called by muse, mutect2, varscan2
- ABLIM2 | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 165/838 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs780667383, COSV56400552, COSV99589634; called by muse, mutect2, varscan2
- ABLIM2 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 73/410 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs765539980, COSV99591048; called by muse, mutect2, varscan2
- ABTB1 | c.985G>A p.V329I (on ENST00000232744 / NM_172027.3; = p.V187I on NM_032548.3) | Missense Mutation (SNP) | VAF 69/505 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.011); catalogued as rs376690383; called by muse, mutect2, varscan2
- ABTB2 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 150/882 reads (17%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.891); catalogued as rs757163576; called by muse, varscan2
- AC005833.1 | c.1582C>T p.R528W | Missense Mutation (SNP) | VAF 57/498 reads (11%) | SIFT deleterious, low confidence (0.03); catalogued as rs776743784, COSV52898635; called by muse, mutect2, varscan2
- AC011448.1 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 132/678 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.588); catalogued as rs1011131163; called by muse, mutect2, varscan2
- AC011455.2 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 91/489 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs748750474, COSV55500335; called by muse, mutect2, varscan2
- AC011462.1 | c.707T>G p.F236C | Missense Mutation (SNP) | VAF 58/524 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as COSV54200560; called by muse, mutect2, varscan2
- AC012488.2 | c.119A>G p.E40G | Missense Mutation (SNP) | VAF 73/647 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.617); catalogued as rs1393780854; called by muse, mutect2, varscan2
- AC013489.1 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 86/410 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as rs778682836, COSV51551922; called by muse, mutect2, varscan2
- AC068580.4 | c.1127A>G p.D376G | Missense Mutation (SNP) | VAF 44/425 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.737); catalogued as rs940998226; called by muse, mutect2, varscan2
- AC068580.4 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 90/753 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.242); catalogued as rs759564989, COSV104377109; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC069544.2 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 20/295 reads (7%) | catalogued as rs1360417732; called by muse, mutect2
- AC097637.1 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 104/481 reads (22%) | catalogued as rs761464663, COSV59727445; called by muse, mutect2, varscan2
- AC098582.1 | c.2444G>A p.G815D | Missense Mutation (SNP) | VAF 185/1047 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV52017917, COSV99985490; called by muse, mutect2, varscan2
- AC131160.1 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 100/469 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.46); catalogued as rs777761061, COSV57700637; called by muse, mutect2, varscan2
- ACACA | c.158A>G p.H53R | Missense Mutation (SNP) | VAF 76/708 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.153); catalogued as rs759985588; called by muse, mutect2, varscan2
- ACACB | c.2894A>G p.D965G | Missense Mutation (SNP) | VAF 32/403 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs1329530168; called by muse, mutect2
- ACAD10 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 111/601 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs936482892, COSV58163358; called by muse, mutect2, varscan2
- ACAD11 | c.1928C>T p.A643V | Missense Mutation (SNP) | VAF 139/923 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs777865245; called by muse, mutect2, varscan2
- ACAD8 | c.1165C>T p.R389W | Missense Mutation (SNP) | VAF 80/914 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542185860, COSV55539632; called by muse, mutect2
- ACADSB | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 155/800 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201451908; called by muse, mutect2, varscan2
- ACADSB | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 87/838 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs745900584, COSV62551468; called by muse, varscan2
- ACAN | c.4573C>A p.L1525I | Missense Mutation (SNP) | VAF 57/513 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0.279); catalogued as rs1185863833; called by muse, mutect2, varscan2
- ACAP2 | c.1289G>A p.G430D | Missense Mutation (SNP) | VAF 163/817 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755798211; called by muse, mutect2, varscan2
- ACAP2 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 102/868 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs779591643, COSV58754703; called by muse, mutect2, varscan2
- ACAT1 | c.940+7C>T | Splice Region (SNP) | VAF 25/389 reads (6%) | catalogued as rs994507837; called by muse, mutect2
- ACCSL | c.554T>C p.M185T | Missense Mutation (SNP) | VAF 106/855 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs746728486; called by muse, mutect2, varscan2
- ACE | c.2654C>T p.A885V | Missense Mutation (SNP) | VAF 78/329 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1251602237, COSV52007782, COSV52008955; called by muse, mutect2, varscan2
- ACE2 | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 112/986 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.323); catalogued as rs140473595; called by muse, mutect2, varscan2
- ACKR2 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 116/560 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1350292551, COSV56177017; called by muse, mutect2, varscan2
- ACKR4 | c.293C>A p.A98D | Missense Mutation (SNP) | VAF 123/722 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99031675; called by mutect2, varscan2
- ACO1 | c.2247C>T p.I749= | Splice Region (SNP) | VAF 208/1011 reads (21%) | catalogued as rs765073565; called by muse, mutect2, varscan2
- ACO1 | c.2633G>A p.G878D | Missense Mutation (SNP) | VAF 86/1243 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59383736; called by muse, mutect2
- ACOT7 | c.424G>A p.V142M (on ENST00000377855 / NM_181864.3; = p.V132M on NM_007274.4) | Missense Mutation (SNP) | VAF 103/660 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs1202082638, COSV100830183; called by muse, mutect2, varscan2
- ACOT9 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 160/768 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs756594878; called by muse, mutect2, varscan2
- ACOX1 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 150/844 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53132392; called by muse, mutect2, varscan2
- ACOX3 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 108/538 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as rs147193447; called by muse, varscan2
- ACOX3 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 102/559 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs556118466; called by muse, varscan2
- ACP4 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 89/412 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54518727; called by muse, mutect2, varscan2
- ACP5 | c.716G>A p.G239D | Missense Mutation (SNP) | VAF 58/324 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773070944; called by muse, varscan2
- ACP6 | c.801C>A p.C267* | Nonsense Mutation (SNP) | VAF 178/983 reads (18%) | catalogued as COSV100984196; called by muse, mutect2, varscan2
- ACSL6 | c.832G>A p.G278S (on ENST00000379240; = p.G303S on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 175/759 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs756995050, COSV57297172; called by muse, mutect2, varscan2
- ACSM1 | c.5A>G p.Q2R | Missense Mutation (SNP) | VAF 58/462 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1215690276; called by muse, mutect2, varscan2
- ACSS2 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 117/684 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs946609628, COSV53624265; called by muse, mutect2, varscan2
- ACTA1 | c.808G>A p.G270S | Missense Mutation (SNP) | VAF 66/460 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as CM012325, CM034511, CM045914, CX095261, COSV64203015; called by muse, mutect2, varscan2
- ACTBL2 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 212/1137 reads (19%) | catalogued as rs1358229735, COSV101379422; called by muse, mutect2, varscan2
- ACTL9 | c.572T>C p.V191A | Missense Mutation (SNP) | VAF 40/253 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as rs782225601; called by muse, mutect2, varscan2
- ACTN2 | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 45/353 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63978756; called by muse, mutect2, varscan2
- ACTR6 | c.67T>C p.S23P | Missense Mutation (SNP) | VAF 49/405 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.686); catalogued as COSV51841133; called by muse, mutect2, varscan2
- ACTR6 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 104/948 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375164278, COSV51842902; called by muse, mutect2, varscan2
- ACTRT2 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 113/731 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs776228150, COSV65758880; called by muse, mutect2, varscan2
- ACTRT3 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 116/996 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs776125776, COSV100377511; called by muse, varscan2
- ACVR1 | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 116/905 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99069414; called by muse, mutect2, varscan2
- ACVR1C | c.722C>T p.T241M | Missense Mutation (SNP) | VAF 32/841 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330939534, COSV99694838; called by muse, mutect2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 281/1480 reads (19%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACYP1 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 107/821 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762735998, COSV53134469; called by muse, mutect2, varscan2
- ADA | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 23/405 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1044335093; called by muse, mutect2
- ADAM10 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 226/1109 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs754468638; called by muse, mutect2, varscan2
- ADAM12 | c.2206C>T p.R736* | Nonsense Mutation (SNP) | VAF 132/845 reads (16%) | catalogued as rs745628072, COSV64104548; called by muse, varscan2
- ADAM12 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 120/780 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs770769845, COSV64106410; called by muse, mutect2, varscan2
- ADAM18 | c.2209G>A p.V737M | Missense Mutation (SNP) | VAF 46/1138 reads (4%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as rs202233805; called by muse, mutect2
- ADAM23 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 129/763 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs778780969, COSV52215929; called by muse, mutect2, varscan2
- ADAM28 | c.10G>A p.G4S | Missense Mutation (SNP) | VAF 87/846 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs772020183, COSV56097343; called by muse, mutect2, varscan2
- ADAM29 | c.1176G>T p.K392N | Missense Mutation (SNP) | VAF 173/1302 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.214); catalogued as COSV63665948; called by muse, mutect2, varscan2
- ADAM8 | c.1802G>A p.R601H | Missense Mutation (SNP) | VAF 74/390 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs777265811; called by muse, mutect2, varscan2
- ADAM9 | c.410+5G>A | Splice Region (SNP) | VAF 69/455 reads (15%) | catalogued as rs1378506446; called by muse, mutect2, varscan2
- ADAM9 | c.833G>A p.G278D | Missense Mutation (SNP) | VAF 106/850 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs1465967321; called by muse, varscan2
- ADAMTS1 | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 210/1107 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs770017773, COSV53170046; called by muse, mutect2, varscan2
- ADAMTS1 | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 42/888 reads (5%) | catalogued as COSV53170410; called by muse, mutect2
- ADAMTS12 | c.3937G>A p.G1313S | Missense Mutation (SNP) | VAF 119/1038 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs568403595; called by muse, mutect2, varscan2
- ADAMTS12 | c.2566C>T p.R856C | Missense Mutation (SNP) | VAF 160/922 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); catalogued as rs148278677, COSV100711781; called by muse, mutect2, varscan2
- ADAMTS12 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 125/903 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201263969, COSV61281223; called by muse, varscan2
- ADAMTS13 | c.3170C>T p.A1057V | Missense Mutation (SNP) | VAF 111/574 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.231); catalogued as rs1056233134, COSV63023009; called by muse, varscan2
- ADAMTS14 | c.779G>A p.S260N | Missense Mutation (SNP) | VAF 57/459 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770574060, COSV100941436; called by muse, varscan2
- ADAMTS14 | c.1972G>A p.V658M | Missense Mutation (SNP) | VAF 187/889 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs753200023; called by muse, mutect2, varscan2
- ADAMTS17 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 163/826 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); catalogued as rs777383202, COSV51479119; called by muse, mutect2, varscan2
- ADAMTS18 | c.2396A>G p.Y799C | Missense Mutation (SNP) | VAF 73/727 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1408250921; called by muse, mutect2, varscan2
- ADAMTS18 | c.1060G>T p.G354* | Nonsense Mutation (SNP) | VAF 41/711 reads (6%) | catalogued as COSV99274582; called by muse, mutect2
- ADAMTS2 | c.2053G>A p.A685T | Missense Mutation (SNP) | VAF 83/544 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as rs367549580, COSV52387833; called by muse, varscan2
- ADAMTS20 | c.5326T>C p.Y1776H | Missense Mutation (SNP) | VAF 122/1276 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.315); catalogued as rs1242310838; called by muse, mutect2
- ADAMTS20 | c.2114C>T p.A705V | Missense Mutation (SNP) | VAF 128/721 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as rs952881488, COSV67129705; called by muse, mutect2, varscan2
- ADAMTS3 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 219/1241 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV99711788; called by muse, mutect2, varscan2
- ADAMTS8 | c.843G>T p.E281D | Missense Mutation (SNP) | VAF 44/670 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV57299314; called by muse, mutect2
- ADAMTS9 | c.3005G>A p.R1002H | Missense Mutation (SNP) | VAF 130/1023 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs377320318; called by muse, mutect2, varscan2
- ADAMTS9 | c.1939C>T p.R647* | Nonsense Mutation (SNP) | VAF 218/1057 reads (21%) | catalogued as rs776836604, COSV55787594; called by muse, mutect2, varscan2
- ADAMTSL1 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 56/510 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs1462538657; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2681C>T p.A894V | Missense Mutation (SNP) | VAF 97/536 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs760078676, COSV65900315; called by muse, mutect2, varscan2
- ADAMTSL4 | c.3019C>T p.R1007* | Nonsense Mutation (SNP) | VAF 67/566 reads (12%) | catalogued as rs768395332; called by muse, mutect2, varscan2
- ADAMTSL5 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 71/345 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs758342918, COSV57860558; called by muse, mutect2, varscan2
- ADARB1 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 122/780 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as rs1303618439; called by muse, varscan2
- ADARB1 | c.2032C>T p.R678C (on ENST00000360697 / NM_001346687.2; = p.R638C on NM_001112.4) | Missense Mutation (SNP) | VAF 79/544 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs1298111041, COSV62348177; called by muse, varscan2
- ADARB2 | c.1586C>T p.T529M | Missense Mutation (SNP) | VAF 86/463 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs933741683, COSV101187605; called by muse, mutect2, varscan2
- ADARB2 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 18/329 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as rs1358010815; called by muse, mutect2
- ADAT3 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 41/335 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs868340074; called by muse, mutect2, varscan2
- ADCK5 | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 104/509 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782531911; called by muse, mutect2, varscan2
- ADCY1 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 248/919 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV52036922; called by muse, varscan2
- ADCY1 | c.1747G>A p.A583T | Missense Mutation (SNP) | VAF 237/1070 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV99813174; called by muse, varscan2
- ADCY10 | c.4345C>A p.L1449I | Missense Mutation (SNP) | VAF 129/806 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs749690491, COSV63239583, COSV63240944, COSV63245296; called by muse, mutect2, varscan2
- ADCY3 | c.2653C>T p.R885* | Nonsense Mutation (SNP) | VAF 89/702 reads (13%) | catalogued as COSV53165881; called by muse, mutect2, varscan2
- ADCY6 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 56/220 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs754623063; called by muse, mutect2, varscan2
- ADCY7 | c.2908G>A p.A970T | Missense Mutation (SNP) | VAF 74/488 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371865539; called by muse, mutect2, varscan2
- ADCY8 | c.2717C>T p.A906V | Missense Mutation (SNP) | VAF 107/675 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as COSV53912834; called by muse, mutect2, varscan2
- ADCY9 | c.1418T>A p.I473N | Missense Mutation (SNP) | VAF 67/484 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750643399; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.557A>C p.N186T | Missense Mutation (SNP) | VAF 122/841 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58442600; called by muse, mutect2, varscan2
- ADGRA2 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 87/531 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs144591273; called by muse, mutect2, varscan2
- ADGRA2 | c.1460T>C p.M487T | Missense Mutation (SNP) | VAF 40/941 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs1235134721; called by muse, mutect2
- ADGRA2 | c.2249C>T p.A750V | Missense Mutation (SNP) | VAF 127/676 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1387474132; called by muse, mutect2, varscan2
- ADGRB1 | c.3655G>A p.A1219T | Missense Mutation (SNP) | VAF 38/358 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs1273962372, COSV60103955; called by muse, varscan2
- ADGRB1 | c.3734G>A p.R1245H | Missense Mutation (SNP) | VAF 138/714 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs1168368243; called by muse, varscan2
- ADGRB2 | c.1703G>A p.R568H | Missense Mutation (SNP) | VAF 130/648 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs768585899; called by muse, varscan2
- ADGRB3 | c.2608-1G>T p.X870_splice | Splice Site (SNP) | VAF 231/1180 reads (20%) | catalogued as COSV99485225; called by muse, varscan2
- ADGRE1 | c.1883G>A p.R628H | Missense Mutation (SNP) | VAF 73/506 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as rs763154666, COSV51678146; called by muse, mutect2, varscan2
- ADGRF2 | c.1826T>C p.I609T (on ENST00000296862 / NM_001368115.2; = p.I541T on NM_153839.7) | Missense Mutation (SNP) | VAF 118/996 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs780643798; called by muse, mutect2, varscan2
- ADGRF4 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 173/846 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536284658, COSV51956797; called by muse, mutect2, varscan2
- ADGRF5 | c.3172G>A p.A1058T | Missense Mutation (SNP) | VAF 112/652 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as rs1307460777; called by muse, mutect2, varscan2
- ADGRG1 | c.1168-1G>A p.X390_splice | Splice Site (SNP) | VAF 32/244 reads (13%) | catalogued as COSV65636292; called by muse, mutect2, varscan2
- ADGRG1 | c.1915G>A p.V639I | Missense Mutation (SNP) | VAF 142/789 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as rs750738167; called by muse, mutect2, varscan2
- ADGRG4 | c.3184G>T p.A1062S | Missense Mutation (SNP) | VAF 179/1094 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV99795669, COSV99797281; called by muse, mutect2, varscan2
- ADGRG5 | c.1519C>T p.R507W | Missense Mutation (SNP) | VAF 79/536 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs777835722, COSV61082756; called by muse, mutect2, varscan2
- ADGRG6 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 54/1360 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV51601098; called by muse, mutect2
- ADGRG6 | c.3376C>T p.R1126W | Missense Mutation (SNP) | VAF 110/1098 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750908671; called by muse, mutect2, varscan2
- ADGRG7 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 136/1037 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.233); catalogued as rs368926208; called by muse, mutect2, varscan2
- ADGRL1 | c.2941G>A p.A981T (on ENST00000340736 / NM_001008701.3; = p.A976T on NM_014921.5) | Missense Mutation (SNP) | VAF 58/437 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as rs1476249887, COSV61564027, COSV61567118; called by muse, varscan2
- ADGRL2 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 112/968 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780914901; called by muse, mutect2, varscan2
- ADGRL3 | c.335G>A p.R112H (on ENST00000506720 / NM_001322402.2; = p.R44H on NM_015236.6) | Missense Mutation (SNP) | VAF 292/1296 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1284975701, COSV72268248; called by muse, varscan2
- ADGRL3 | c.352G>A p.V118I (on ENST00000506720 / NM_001322402.2; = p.V50I on NM_015236.6) | Missense Mutation (SNP) | VAF 251/1341 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs547873129, COSV101546933; called by muse, mutect2, varscan2
- ADGRL3 | c.4652G>T p.S1551I (on ENST00000506720 / NM_001322402.2; = p.S1440I on NM_015236.6) | Missense Mutation (SNP) | VAF 136/1368 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); catalogued as rs957462955; called by muse, mutect2
- ADGRV1 | c.950A>G p.Q317R | Missense Mutation (SNP) | VAF 78/1386 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.218); catalogued as rs1232447223; called by muse, mutect2
- ADGRV1 | c.6884C>T p.A2295V | Missense Mutation (SNP) | VAF 160/1247 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.718); catalogued as rs1247514195; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.7609A>G p.S2537G | Missense Mutation (SNP) | VAF 128/1171 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.827); catalogued as COSV67991825; called by muse, varscan2
- ADGRV1 | c.17107C>T p.R5703C | Missense Mutation (SNP) | VAF 250/1260 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs761963239, COSV67981620; called by muse, varscan2
- ADH1C | c.863G>A p.G288D | Missense Mutation (SNP) | VAF 96/729 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1423604859, COSV101565191; called by muse, mutect2, varscan2
- ADH1C | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 236/1229 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs760614352; called by muse, mutect2, varscan2
- ADIPOR1 | c.807C>T p.G269= | Splice Region (SNP) | VAF 76/420 reads (18%) | catalogued as rs763154047, COSV61851560; called by muse, mutect2, varscan2
- ADORA3 | c.691T>C p.S231P | Missense Mutation (SNP) | VAF 60/982 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53984968; called by muse, mutect2
- ADPRH | c.842C>A p.A281D | Missense Mutation (SNP) | VAF 169/759 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63695968; called by muse, mutect2, varscan2
- ADPRHL1 | c.220T>C p.W74R | Missense Mutation (SNP) | VAF 54/339 reads (16%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.776); catalogued as rs1413506891; called by muse, mutect2, varscan2
- ADRA1B | c.257A>G p.N86S | Missense Mutation (SNP) | VAF 81/770 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); catalogued as rs768822216; called by muse, mutect2, varscan2
- ADRA1D | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 69/391 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1192475463, COSV65241196; called by muse, mutect2, varscan2
- ADRA2A | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 95/652 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54528580; called by muse, mutect2, varscan2
- ADRA2A | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 133/747 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs764891418, COSV54527528; called by muse, mutect2, varscan2
- ADRA2B | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 102/547 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1374379079, COSV69787249; called by muse, mutect2, varscan2
- ADRA2B | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 48/369 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1262534626; called by muse, varscan2
- ADRB2 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 126/752 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100019235; called by muse, varscan2
- ADRB3 | c.214A>G p.T72A | Missense Mutation (SNP) | VAF 33/276 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1341794632; called by muse, mutect2, varscan2
- AEN | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 61/379 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs748456814; called by muse, mutect2, varscan2
- AF196969.1 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 32/324 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.115); catalogued as rs782456649; called by muse, varscan2
- AFDN | c.4858C>T p.R1620C (on ENST00000447894 / NM_001366320.1; = p.R1618C on NM_001040000.3) | Missense Mutation (SNP) | VAF 59/1394 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV60039779; called by muse, mutect2
- AFF3 | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 49/386 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1476255226, COSV57865176; called by muse, mutect2, varscan2
- AFG1L | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 148/1200 reads (12%) | SIFT tolerated (0.87); PolyPhen benign (0.078); catalogued as rs756443552, COSV64555663; called by muse, varscan2
- AFMID | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 111/467 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs926323806, COSV59975724; called by muse, mutect2, varscan2
- AFP | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 160/983 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs367853668; called by muse, mutect2, varscan2
- AGAP2 | c.1622G>A p.R541H (on ENST00000547588 / NM_001122772.2; = p.R205H on NM_014770.4) | Missense Mutation (SNP) | VAF 86/692 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as rs371402878, COSV57727025; called by muse, varscan2
- AGAP4 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 112/758 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.501); catalogued as rs1422901360; called by muse, mutect2, varscan2
- AGAP6 | c.340C>T p.R114C (on ENST00000374056 / NM_001365867.1; = p.R137C on NM_001077665.2) | Missense Mutation (SNP) | VAF 37/908 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.689); catalogued as rs782043801, COSV65018283; called by muse, mutect2
- AGAP6 | c.805C>T p.R269* (on ENST00000374056 / NM_001365867.1; = p.R292* on NM_001077665.2) | Nonsense Mutation (SNP) | VAF 75/417 reads (18%) | catalogued as rs782351142, COSV100929165; called by muse, mutect2, varscan2
- AGBL4 | c.1384C>A p.Q462K | Missense Mutation (SNP) | VAF 41/832 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1008847859, COSV61891357; called by muse, mutect2
- AGBL4 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 87/766 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV61893378; called by muse, mutect2, varscan2
- AGBL5 | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 131/608 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765173040; called by muse, mutect2, varscan2
- AGFG2 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 109/532 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as rs1394768111; called by muse, mutect2, varscan2
- AGGF1 | c.519G>A p.E173= | Splice Region (SNP) | VAF 166/570 reads (29%) | catalogued as rs1327475737; called by muse, mutect2, varscan2
- AGL | c.3347G>A p.R1116H | Missense Mutation (SNP) | VAF 158/751 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746779518; called by muse, mutect2, varscan2
- AGL | c.4075C>T p.R1359C | Missense Mutation (SNP) | VAF 158/1361 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs146257941; called by muse, mutect2, varscan2
- AGO1 | c.2560A>G p.M854V | Missense Mutation (SNP) | VAF 126/723 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.694); catalogued as COSV64595114; called by muse, mutect2, varscan2
- AGO2 | c.1358T>C p.I453T | Missense Mutation (SNP) | VAF 45/438 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1323817642; called by muse, mutect2
- AGO2 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 69/1224 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV55045110; called by muse, mutect2
- AGPAT1 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 126/645 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100421523; called by muse, mutect2, varscan2
- AGRN | c.3736C>T p.R1246* | Nonsense Mutation (SNP) | VAF 78/460 reads (17%) | catalogued as COSV101038612; called by muse, mutect2
- AGTPBP1 | c.2825C>T p.P942L (on ENST00000357081 / NM_001330701.2; = p.P902L on NM_015239.2) | Missense Mutation (SNP) | VAF 211/1185 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.438); catalogued as rs771158224; called by muse, mutect2, varscan2
- AGTR1 | c.140G>A p.S47N | Missense Mutation (SNP) | VAF 214/1167 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV62560266; called by muse, mutect2, varscan2
- AGTR1 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 155/1288 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs570056677, COSV62560384; called by muse, mutect2, varscan2
- AHCTF1 | c.3533C>T p.P1178L (on ENST00000366508; = p.P1152L on NM_015446.5) | Missense Mutation (SNP) | VAF 173/952 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.716); catalogued as COSV100404179; called by muse, varscan2
- AHCTF1 | c.1541C>T p.A514V (on ENST00000366508; = p.A488V on NM_015446.5) | Missense Mutation (SNP) | VAF 116/726 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.134); catalogued as rs1350334323; called by muse, mutect2, varscan2
- AHCYL2 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 202/1122 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs1175608941, COSV61484835; called by muse, varscan2
- AHNAK | c.14873T>C p.M4958T | Missense Mutation (SNP) | VAF 78/751 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs762785114, COSV57221976; called by muse, mutect2, varscan2
- AHNAK2 | c.16342C>T p.P5448S | Missense Mutation (SNP) | VAF 67/501 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV60910749; called by muse, mutect2, varscan2
- AHNAK2 | c.11012A>G p.D3671G | Missense Mutation (SNP) | VAF 83/463 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV60910347; called by muse, mutect2, varscan2
- AHNAK2 | c.10499C>T p.A3500V | Missense Mutation (SNP) | VAF 47/246 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs374100559; called by muse, mutect2, varscan2
- AHNAK2 | c.7883C>T p.A2628V | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs200418445, COSV60929411; called by muse, mutect2, varscan2
- AHRR | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 91/571 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs369824795; called by muse, mutect2, varscan2
- AIPL1 | c.784+4C>T | Splice Region (SNP) | VAF 79/390 reads (20%) | catalogued as rs375600133; called by muse, mutect2, varscan2
- AIRE | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 103/533 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs372604287; called by muse, mutect2, varscan2
- AJM1 | c.2164G>A p.V722I | Missense Mutation (SNP) | VAF 96/430 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.021); catalogued as rs769464283; called by muse, mutect2, varscan2
- AJM1 | c.2387C>T p.A796V | Missense Mutation (SNP) | VAF 89/384 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.407); catalogued as rs778752250; called by muse, mutect2, varscan2
- AK1 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 56/261 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1433788041; called by muse, mutect2, varscan2
- AK5 | c.1424G>A p.R475H (on ENST00000354567 / NM_174858.3; = p.R449H on NM_012093.4) | Missense Mutation (SNP) | VAF 70/674 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs769633875, COSV60977121; called by muse, varscan2
- AK5 | c.1525G>A p.D509N (on ENST00000354567 / NM_174858.3; = p.D483N on NM_012093.4) | Missense Mutation (SNP) | VAF 85/657 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.497); catalogued as rs750300175, COSV60976281; called by muse, mutect2, varscan2
- AK5 | c.1588G>A p.A530T (on ENST00000354567 / NM_174858.3; = p.A504T on NM_012093.4) | Missense Mutation (SNP) | VAF 107/798 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs1335114276; called by muse, varscan2
- AKAP10 | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 110/529 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.382); catalogued as rs865801175; called by muse, mutect2, varscan2
- AKAP12 | c.1921G>A p.A641T | Missense Mutation (SNP) | VAF 147/817 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as rs753094802, COSV53571409; called by muse, varscan2
- AKAP17A | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 87/476 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); catalogued as rs778914741, COSV58309509; called by muse, mutect2, varscan2
- AKAP4 | c.2119C>T p.L707F | Missense Mutation (SNP) | VAF 106/798 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557203788, COSV62074313; called by muse, mutect2, varscan2
- AKAP4 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 155/828 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs1486445723; called by muse, mutect2, varscan2
- AKAP8L | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101275907; called by muse, mutect2, varscan2
- AKAP8L | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 22/404 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1223522757, COSV68473042; called by muse, mutect2
- AKAP9 | c.9184C>T p.R3062C (on ENST00000359028; = p.R3038C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 127/1307 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs753467156, COSV62347967; ClinVar: uncertain significance; called by muse, mutect2
- AKIP1 | c.608G>A p.S203N | Missense Mutation (SNP) | VAF 183/988 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as rs531227382; called by muse, mutect2, varscan2
- AKR1C1 | c.258G>A p.W86* | Nonsense Mutation (SNP) | VAF 210/1123 reads (19%) | catalogued as rs143557246; called by muse, mutect2, varscan2
- AKR1C2 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 116/960 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as rs1277254274; called by muse, mutect2, varscan2
- AKT1 | c.828G>A p.K276= | Splice Region (SNP) | VAF 91/450 reads (20%) | catalogued as rs775212616; called by muse, mutect2, varscan2
- AKT1 | c.287+5G>A | Splice Region (SNP) | VAF 88/427 reads (21%) | catalogued as rs373853807; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKT1S1 | c.599C>T p.A200V (on ENST00000344175 / NM_001098633.4; = p.A220V on NM_032375.5) | Missense Mutation (SNP) | VAF 139/699 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.086); catalogued as rs142575650; called by muse, mutect2, varscan2
- AL121899.2 | c.1745A>G p.Y582C | Missense Mutation (SNP) | VAF 29/598 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV67351419; called by muse, mutect2
- AL355102.2 | c.207G>A p.W69* | Nonsense Mutation (SNP) | VAF 75/626 reads (12%) | catalogued as rs369051092; called by muse, mutect2, varscan2
- AL358113.1 | c.3887G>A p.R1296H | Missense Mutation (SNP) | VAF 151/787 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs370985421, COSV61957484; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AL441992.2 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 89/466 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs953720761, COSV56912235; called by muse, varscan2
- AL592490.1 | c.2595A>G p.I865M | Missense Mutation (SNP) | VAF 77/727 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as COSV69425847; called by muse, varscan2
- AL592490.1 | c.2572A>G p.R858G | Missense Mutation (SNP) | VAF 94/802 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV69424860, COSV69426585; called by muse, varscan2
- AL592490.1 | c.1310G>A p.G437D | Missense Mutation (SNP) | VAF 96/1422 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs1043182473; called by muse, mutect2
- AL592490.1 | c.188G>A p.S63N | Missense Mutation (SNP) | VAF 120/1017 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV101308295; called by muse, mutect2, varscan2
- AL645922.1 | c.3627G>T p.K1209N | Missense Mutation (SNP) | VAF 101/842 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV64888366; called by muse, mutect2, varscan2
- ALAS1 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 97/613 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs773336919, COSV59626776; called by muse, mutect2, varscan2
- ALDH18A1 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 150/634 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375122662; called by muse, mutect2, varscan2
- ALDH1B1 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 125/318 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as rs770868005, COSV66620743; called by muse, mutect2, varscan2
- ALDH1L1 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 82/606 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs753739852; called by muse, varscan2
- ALDH1L2 | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 105/528 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.616); catalogued as rs1367381649; called by muse, mutect2, varscan2
- ALDH2 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 119/655 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); catalogued as rs923192135, COSV55668856; called by muse, mutect2, varscan2
- ALDH3A2 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 149/1162 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs370654268; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH8A1 | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 65/539 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs150799987; called by muse, mutect2, varscan2
- ALDOA | c.1001C>T p.A334V (on ENST00000642816 / NM_001243177.4; = p.A280V on NM_184041.5) | Missense Mutation (SNP) | VAF 97/524 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as CM1413747; called by muse, mutect2, varscan2
- ALG1 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 57/453 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52159617; called by muse, mutect2, varscan2
- ALG2 | c.1219C>T p.L407F | Missense Mutation (SNP) | VAF 139/747 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs148332697; called by muse, mutect2, varscan2
- ALG2 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 267/1193 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53059154; called by muse, mutect2, varscan2
- ALG3 | c.1010-6G>A | Splice Region (SNP) | VAF 114/609 reads (19%) | catalogued as rs750517699; called by muse, mutect2, varscan2
- ALK | c.3641G>A p.R1214H | Missense Mutation (SNP) | VAF 65/553 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as rs750194005, COSV66583891; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALKBH7 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 75/395 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs768898380; called by muse, mutect2, varscan2
- ALMS1 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 308/1562 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.102); catalogued as rs370830919; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALMS1 | c.10816C>T p.R3606W | Missense Mutation (SNP) | VAF 239/1231 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1250097723; called by muse, mutect2, varscan2
- ALPG | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 145/681 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as rs1360147831; called by muse, mutect2, varscan2
- ALPI | c.1244G>A p.G415D | Missense Mutation (SNP) | VAF 91/552 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55015230; called by muse, mutect2, varscan2
- ALPI | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 50/359 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV55014317; called by muse, mutect2, varscan2
- ALPK2 | c.6283A>G p.T2095A | Missense Mutation (SNP) | VAF 55/485 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs149775332; called by muse, mutect2, varscan2
- ALS2CL | c.2407C>T p.L803F | Missense Mutation (SNP) | VAF 34/794 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1227088882; called by muse, mutect2
- AMBRA1 | c.3670C>T p.R1224* (on ENST00000458649 / NM_001367468.1; = p.R1134* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 82/407 reads (20%) | catalogued as rs1023861260, COSV54053486; called by muse, mutect2, varscan2
- AMDHD1 | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 46/692 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1427756850; called by muse, mutect2
- AMDHD2 | c.1216G>A p.A406T (on ENST00000293971 / NM_001330449.2; = p.A436T on NM_015944.4) | Missense Mutation (SNP) | VAF 76/368 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as rs1467310280, COSV53550335; called by muse, mutect2, varscan2
- AMER1 | c.3004T>C p.S1002P | Missense Mutation (SNP) | VAF 118/651 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV57662850; called by muse, mutect2, varscan2
- AMER1 | c.2111G>A p.R704H | Missense Mutation (SNP) | VAF 103/662 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.952); catalogued as rs768098639; called by muse, mutect2, varscan2
- AMIGO2 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 131/1228 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs768600639; called by muse, mutect2, varscan2
- AMMECR1 | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 115/658 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1331046485; called by muse, mutect2, varscan2
- AMOTL2 | c.2083G>A p.A695T | Missense Mutation (SNP) | VAF 89/666 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs372900931; called by muse, mutect2, varscan2
- AMOTL2 | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 78/646 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs761943709; called by muse, mutect2, varscan2
- AMPD1 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 146/821 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775559099; called by muse, mutect2, varscan2
- AMPD3 | c.992G>A p.R331H (on ENST00000396553 / NM_001025389.2; = p.R340H on NM_000480.3) | Missense Mutation (SNP) | VAF 56/916 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs1425942523, COSV67331273; called by muse, mutect2
- AMPH | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 190/869 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV57740032; called by muse, mutect2, varscan2
- AMPH | c.980A>G p.N327S | Missense Mutation (SNP) | VAF 73/1729 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.767); catalogued as rs1408270664; called by muse, mutect2
- AMY2A | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 413/2722 reads (15%) | catalogued as rs566657194; called by muse, mutect2, varscan2
- AMY2A | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 237/2998 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs763068700, COSV70214694; called by muse, mutect2
- ANAPC1 | c.4879A>G p.N1627D | Missense Mutation (SNP) | VAF 50/467 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as rs1240524433; called by muse, mutect2, varscan2
- ANAPC5 | c.1799C>T p.A600V | Missense Mutation (SNP) | VAF 76/793 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.943); catalogued as rs369898477; called by muse, mutect2
- ANAPC7 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 34/733 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs939569596, COSV101482828; called by muse, mutect2
- ANGEL1 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 85/619 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs375071846; called by muse, mutect2, varscan2
- ANGEL1 | c.719G>A p.G240D | Missense Mutation (SNP) | VAF 99/524 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV51873889; called by muse, mutect2, varscan2
- ANGPT4 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 59/330 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.104); catalogued as rs543557667, COSV67921944; called by muse, varscan2
- ANGPT4 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 92/498 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs780729817; called by muse, mutect2, varscan2
- ANGPTL4 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 49/309 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.974); catalogued as rs750402576, COSV56844260; called by muse, mutect2, varscan2
- ANK1 | c.4712C>T p.A1571V | Missense Mutation (SNP) | VAF 75/562 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.102); catalogued as rs376400988; called by muse, mutect2, varscan2
- ANK1 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 126/640 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs746138074, COSV55886993; called by muse, mutect2, varscan2
- ANK2 | c.745G>C p.A249P | Missense Mutation (SNP) | VAF 56/1598 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52175731, COSV52195154; called by muse, mutect2
- ANK2 | c.3007C>T p.R1003* | Nonsense Mutation (SNP) | VAF 52/1114 reads (5%) | catalogued as COSV52156986; called by muse, mutect2
- ANK2 | c.5806C>T p.R1936C | Missense Mutation (SNP) | VAF 164/1287 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); catalogued as rs201325557, COSV52180309; called by muse, mutect2, varscan2
- ANK2 | c.6082C>T p.R2028W | Missense Mutation (SNP) | VAF 227/1580 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs1411026310, COSV52150851; called by muse, mutect2, varscan2
- ANK2 | c.7369C>T p.P2457S | Missense Mutation (SNP) | VAF 228/1178 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100004105; called by muse, mutect2, varscan2
- ANK2 | c.8726C>T p.P2909L | Missense Mutation (SNP) | VAF 374/1914 reads (20%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.015); catalogued as COSV100004794; called by muse, mutect2, varscan2
- ANK2 | c.9914C>A p.P3305H | Missense Mutation (SNP) | VAF 181/1112 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV100002965; called by muse, mutect2, varscan2
- ANK3 | c.11155C>T p.R3719C | Missense Mutation (SNP) | VAF 114/568 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as rs532004139, COSV55048016; called by muse, varscan2
- ANK3 | c.4664C>T p.A1555V | Missense Mutation (SNP) | VAF 161/1391 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.788); catalogued as rs765064777; called by muse, mutect2, varscan2
- ANK3 | c.3361C>T p.R1121C (on ENST00000280772 / NM_001320874.2; = p.R255C on NM_001149.3) | Missense Mutation (SNP) | VAF 92/624 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759013111, COSV55064344; called by muse, varscan2
- ANK3 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 118/684 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763407504; called by muse, mutect2, varscan2
- ANKAR | c.3476G>A p.R1159H | Missense Mutation (SNP) | VAF 116/797 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs752651499, COSV55619409; called by muse, mutect2, varscan2
- ANKDD1A | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs367982055; called by muse, mutect2, varscan2
- ANKFY1 | c.2110G>A p.A704T (on ENST00000341657 / NM_001330063.2; = p.A705T on NM_016376.5) | Missense Mutation (SNP) | VAF 97/565 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs1442615858, COSV58915465; called by muse, mutect2, varscan2
- ANKFY1 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 45/390 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.962); catalogued as rs759043379, COSV100492303; called by muse, mutect2, varscan2
- ANKH | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 136/752 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.474); catalogued as rs776696718; called by muse, varscan2
- ANKMY2 | c.700A>G p.N234D | Missense Mutation (SNP) | VAF 294/1373 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.03); catalogued as rs1216057339; called by muse, mutect2, varscan2
- ANKRD10 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 40/681 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1377282087; called by muse, mutect2
- ANKRD11 | c.6445G>A p.A2149T | Missense Mutation (SNP) | VAF 114/652 reads (17%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.026); catalogued as rs1024078594, COSV56357358; called by muse, varscan2
- ANKRD11 | c.6319C>T p.R2107C | Missense Mutation (SNP) | VAF 65/340 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs780905536; called by muse, varscan2
- ANKRD11 | c.2075A>G p.D692G | Missense Mutation (SNP) | VAF 194/1998 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as rs1369924058, COSV56357622; called by muse, mutect2
- ANKRD11 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 115/548 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.066); catalogued as rs949172972, COSV56372489; called by muse, mutect2, varscan2
- ANKRD12 | c.5576A>G p.Q1859R | Missense Mutation (SNP) | VAF 129/956 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs369087314; called by muse, mutect2, varscan2
- ANKRD17 | c.7087G>A p.A2363T | Missense Mutation (SNP) | VAF 154/955 reads (16%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs762523913, COSV58225634; called by muse, mutect2, varscan2
- ANKRD27 | c.2449G>A p.A817T | Missense Mutation (SNP) | VAF 53/430 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762117215, COSV60136125; called by muse, mutect2, varscan2
- ANKRD27 | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 93/464 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs780979164, COSV60129683; called by muse, mutect2, varscan2
- ANKRD28 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 124/753 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs758141062; called by muse, mutect2, varscan2
- ANKRD28 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 46/412 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.219); catalogued as rs1485915115, COSV67518335; called by muse, mutect2, varscan2
- ANKRD28 | c.626C>A p.P209H | Missense Mutation (SNP) | VAF 99/920 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1316220741; called by muse, mutect2, varscan2
- ANKRD31 | c.3662G>T p.G1221V | Missense Mutation (SNP) | VAF 163/866 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57159463; called by muse, varscan2
- ANKRD34B | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 214/1207 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865951841, COSV58614314; called by muse, mutect2, varscan2
- ANKRD35 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 32/858 reads (4%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.758); catalogued as rs370459651, COSV62910939; called by muse, mutect2
- ANKRD36 | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 156/1346 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.971); catalogued as COSV101347145; called by muse, mutect2, varscan2
- ANKRD40 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 159/721 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs754612575; called by muse, mutect2, varscan2
- ANKRD42 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 219/1072 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.244); catalogued as rs1486485475; called by muse, mutect2, varscan2
- ANKRD44 | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 108/584 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as rs754432821; called by muse, varscan2
- ANKRD50 | c.2342G>A p.G781D | Missense Mutation (SNP) | VAF 130/1270 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV72385367; called by muse, varscan2
- ANKRD52 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 54/461 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.117); catalogued as rs1381126304; called by muse, mutect2, varscan2
- ANKRD53 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 74/563 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1553424381; called by muse, mutect2, varscan2
- ANKRD6 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 110/880 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs200814043; called by muse, varscan2
- ANKRD6 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 54/536 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1430229730; called by muse, mutect2
- ANKRD60 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 184/893 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as rs1409942391; called by muse, mutect2, varscan2
- ANKRD63 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 25/416 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); catalogued as rs1488593666; called by muse, mutect2
- ANKS1A | c.2248C>T p.R750W | Missense Mutation (SNP) | VAF 49/384 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as rs768221852, COSV64461457; called by muse, mutect2, varscan2
- ANKS1A | c.2905C>T p.R969W | Missense Mutation (SNP) | VAF 107/527 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200225104; called by muse, mutect2, varscan2
- ANKS1B | c.2102A>G p.Q701R | Missense Mutation (SNP) | VAF 234/1183 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs750291571, COSV61336140; called by muse, mutect2, varscan2
- ANKS6 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 108/574 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62049794; called by muse, mutect2, varscan2
- ANLN | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 64/1456 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs1448222736; called by muse, mutect2
- ANO3 | c.2918G>A p.G973D | Missense Mutation (SNP) | VAF 64/1394 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.335); catalogued as rs1256951874; called by muse, mutect2
- ANO4 | c.1076G>A p.G359D (on ENST00000392977 / NM_001286615.2; = p.G324D on NM_178826.4) | Missense Mutation (SNP) | VAF 58/1184 reads (5%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.992); catalogued as COSV54586276; called by muse, mutect2
- ANO7 | c.262G>A p.A88T (on ENST00000274979; = p.A34T on NM_001001666.4) | Missense Mutation (SNP) | VAF 78/338 reads (23%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs773907613; called by muse, mutect2, varscan2
- ANO7 | c.1271T>C p.V424A (on ENST00000274979; = p.V370A on NM_001370694.2) | Missense Mutation (SNP) | VAF 80/476 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51470651; called by muse, mutect2, varscan2
- ANO7 | c.1708G>A p.V570I (on ENST00000274979; = p.V516I on NM_001370694.2) | Missense Mutation (SNP) | VAF 87/455 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as rs148576854; called by muse, mutect2, varscan2
- ANO9 | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 127/712 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as rs1172720468, COSV100230324; called by muse, mutect2, varscan2
- ANPEP | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 50/560 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765125618, COSV55591819; called by muse, mutect2
- ANTXR2 | c.1003G>A p.G335S | Missense Mutation (SNP) | VAF 226/1408 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs753101338, COSV56312795; called by muse, mutect2, varscan2
- ANXA10 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 208/1063 reads (20%) | catalogued as rs570015519; called by muse, mutect2, varscan2
- ANXA11 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 168/858 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750665318; called by muse, varscan2
- ANXA13 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 38/816 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.167); catalogued as rs1158464506, COSV51626318; called by muse, mutect2
- ANXA8 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 48/367 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1428700586; called by muse, mutect2, varscan2
- AOC2 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 86/398 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as rs376110853; called by muse, varscan2
- AOC2 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 98/472 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs200887039, COSV53826256; called by muse, mutect2, varscan2
- AOC2 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 53/369 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as rs267604890, COSV53827971; called by muse, varscan2
- AOC2 | c.1790G>A p.R597H | Missense Mutation (SNP) | VAF 50/404 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs780166614, COSV104389486, COSV53826786; called by muse, varscan2
- AOX1 | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 148/1282 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as rs752882911, COSV65981708; called by muse, mutect2, varscan2
- AOX1 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 145/783 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as rs1348592769; called by muse, varscan2
- AP1B1 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 121/929 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1320742734; called by muse, mutect2, varscan2
- AP1G2 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 122/709 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs762507438, COSV58113909; called by muse, mutect2, varscan2
- AP2A1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 65/374 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV62817197, COSV62820811; called by muse, mutect2, varscan2
- AP3B2 | c.2270C>T p.A757V | Missense Mutation (SNP) | VAF 142/724 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs375481337; called by muse, mutect2, varscan2
- AP3M1 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 198/1051 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.668); catalogued as rs748019786; called by muse, mutect2, varscan2
- AP4B1 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 186/1003 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs750402059, COSV99870648; called by muse, varscan2
- AP4B1 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 103/541 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs968023503; called by muse, mutect2, varscan2
- AP4E1 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 95/489 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as rs151135245; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP4E1 | c.1469A>G p.Y490C | Missense Mutation (SNP) | VAF 111/830 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.89); catalogued as rs1250518787; called by muse, mutect2, varscan2
- AP5B1 | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 142/457 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146521709; called by muse, mutect2, varscan2
- AP5B1 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 115/446 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.344); catalogued as rs1381363830; called by muse, mutect2, varscan2
- AP5M1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 170/912 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.132); catalogued as COSV99841155, COSV99841264; called by muse, varscan2
- AP5S1 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 57/293 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs143505011; called by muse, mutect2, varscan2
- AP5Z1 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 99/584 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs761542147, COSV62241767; called by muse, mutect2, varscan2
- APBA1 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 32/792 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs760771546, COSV55226831; called by muse, mutect2
- APBA1 | c.1106A>G p.Y369C | Missense Mutation (SNP) | VAF 23/475 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99597022; called by muse, mutect2
- APBA1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 38/333 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as COSV55231124, COSV55232935; called by muse, mutect2, varscan2
- APBA2 | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 93/455 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68788804; called by muse, mutect2, varscan2
- APBA3 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 93/535 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs911530503; called by muse, mutect2, varscan2
- APC | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 137/991 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as rs1554079159, COSV57335635; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.5264C>T p.A1755V | Missense Mutation (SNP) | VAF 183/1125 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771967537, COSV57385301; ClinVar: likely benign / uncertain significance; called by muse, varscan2
- APC | c.5540C>T p.T1847M | Missense Mutation (SNP) | VAF 232/1282 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371686531; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.8140C>T p.R2714C | Missense Mutation (SNP) | VAF 138/856 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs864622205, COSV57331764; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC2 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 68/314 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771831923; called by muse, varscan2
- APC2 | c.2830C>A p.P944T | Missense Mutation (SNP) | VAF 57/246 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs754791539; called by muse, mutect2, varscan2
- APC2 | c.3521C>T p.P1174L | Missense Mutation (SNP) | VAF 51/271 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as rs1326407761; called by muse, mutect2, varscan2
- APEH | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 97/502 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.348); catalogued as COSV99610687; called by muse, mutect2, varscan2
- APEX2 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 60/1410 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.106); catalogued as rs866601451, COSV66624500; called by muse, mutect2
- APH1A | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 84/456 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as rs782658182, COSV99354257; called by muse, mutect2, varscan2
- API5 | c.1492+6C>T | Splice Region (SNP) | VAF 53/915 reads (6%) | catalogued as rs1455592378; called by muse, mutect2
- APLN | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 132/566 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758766922, COSV100278253; called by muse, mutect2, varscan2
- APLNR | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 93/452 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs758486436, COSV57242880; called by muse, mutect2, varscan2
- APLP1 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 47/331 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as rs747466333; called by muse, mutect2, varscan2
- APLP1 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs200771936, COSV55701978; called by muse, varscan2
- APLP2 | c.2218C>T p.R740C | Missense Mutation (SNP) | VAF 138/666 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1374684943, COSV53839510; called by muse, mutect2, varscan2
- APMAP | c.155T>C p.V52A | Missense Mutation (SNP) | VAF 52/1399 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as rs1236120986; called by muse, mutect2
- APOA2 | c.-23C>A | Splice Region (SNP) | VAF 49/296 reads (17%) | catalogued as rs1227034667, COSV99248472; called by muse, mutect2, varscan2
- APOA4 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 123/574 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs753407230, COSV63360319; called by muse, mutect2, varscan2
- APOA5 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 103/617 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as rs370089477, CM119846; called by muse, mutect2, varscan2
- APOB | c.10825T>C p.S3609P | Missense Mutation (SNP) | VAF 222/1216 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV51928571; called by muse, mutect2, varscan2
- APOB | c.9988T>A p.F3330I | Missense Mutation (SNP) | VAF 209/1249 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.138); catalogued as COSV99266776; called by muse, mutect2, varscan2
- APOB | c.6475G>A p.A2159T | Missense Mutation (SNP) | VAF 213/1079 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.695); catalogued as COSV51933042; called by muse, mutect2, varscan2
- APOB | c.6318A>T p.Q2106H | Missense Mutation (SNP) | VAF 67/1399 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.906); catalogued as COSV51937808; called by muse, mutect2
- APOB | c.3473G>A p.G1158D | Missense Mutation (SNP) | VAF 62/1194 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs1465111409; called by muse, mutect2
- APOB | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 175/1086 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.035); catalogued as COSV51953279; called by muse, mutect2, varscan2
- APOBEC1 | c.667C>A p.L223I | Missense Mutation (SNP) | VAF 170/893 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99981233; called by muse, mutect2, varscan2
- APOBR | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 77/356 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.234); catalogued as COSV100112339; called by muse, mutect2, varscan2
- APOC3 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 137/737 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.243); catalogued as rs1277092877; called by muse, mutect2, varscan2
- APOL3 | c.512G>A p.R171H (on ENST00000349314 / NM_145640.2; = p.R100H on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 196/967 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as rs577244594, COSV62579985; called by muse, mutect2, varscan2
- APOL5 | c.604G>T p.A202S | Missense Mutation (SNP) | VAF 116/716 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1026661224, COSV99968424; called by muse, mutect2, varscan2
- APOL6 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 105/578 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.127); catalogued as rs760414599, COSV68749620; called by muse, mutect2, varscan2
- APPL1 | c.1745G>A p.R582H | Missense Mutation (SNP) | VAF 219/1058 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs778843447; called by muse, mutect2, varscan2
- APPL2 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 112/711 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs749454008; called by muse, mutect2, varscan2
- AQP10 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 106/653 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99050843; called by muse, mutect2, varscan2
- AQP4 | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 187/1019 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV67218823, COSV67219535; called by muse, mutect2, varscan2
- AQP4 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 193/1141 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148498248; called by muse, mutect2, varscan2
- AQP7 | c.735G>T p.Q245H | Missense Mutation (SNP) | VAF 88/635 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV99953455; called by muse, mutect2, varscan2
- AQP7 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs62542746; called by muse, mutect2, varscan2
- AQR | c.4328G>A p.G1443E | Missense Mutation (SNP) | VAF 73/543 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1361555295; called by muse, mutect2, varscan2
- AQR | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 160/908 reads (18%) | catalogued as rs776826589; called by muse, varscan2
- ARAF | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 87/446 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as COSV51695930; called by muse, mutect2, varscan2
- ARCN1 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 132/673 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as rs147950670; called by muse, mutect2, varscan2
- AREL1 | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 141/760 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1268969629; called by muse, mutect2, varscan2
- AREL1 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 46/304 reads (15%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs1383537786; called by muse, varscan2
- ARFGAP2 | c.942-5C>T | Splice Region (SNP) | VAF 96/612 reads (16%) | catalogued as rs372979011; called by muse, mutect2, varscan2
- ARFGEF1 | c.4247G>A p.G1416D | Missense Mutation (SNP) | VAF 146/891 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51614578; called by muse, mutect2, varscan2
- ARFGEF2 | c.1462A>G p.T488A | Missense Mutation (SNP) | VAF 75/660 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.196); catalogued as rs1281713053; called by muse, mutect2, varscan2
- ARFGEF2 | c.3034C>T p.R1012C | Missense Mutation (SNP) | VAF 199/958 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs758071330; called by muse, mutect2, varscan2
- ARFGEF2 | c.5184C>T p.F1728= | Splice Region (SNP) | VAF 76/447 reads (17%) | catalogued as rs1214696854, COSV64213336; called by muse, mutect2, varscan2
- ARFGEF3 | c.3613C>T p.R1205C | Missense Mutation (SNP) | VAF 196/876 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1463983013, COSV104381395; called by muse, mutect2, varscan2
- ARFIP1 | c.922C>T p.R308C (on ENST00000353617 / NM_001287432.1; = p.R276C on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 280/1414 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367792760; called by muse, mutect2, varscan2
- ARGLU1 | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 116/671 reads (17%) | catalogued as COSV62271750; called by muse, mutect2, varscan2
- ARHGAP1 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 72/333 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs541312809, COSV61734724; called by muse, mutect2, varscan2
- ARHGAP10 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 82/709 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs756616736, COSV60595224; called by muse, mutect2, varscan2
- ARHGAP10 | c.2003G>A p.S668N | Missense Mutation (SNP) | VAF 101/940 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs148488452; called by muse, mutect2, varscan2
- ARHGAP11A | c.1805C>T p.A602V | Missense Mutation (SNP) | VAF 110/999 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs972707513, COSV64380639; called by muse, mutect2, varscan2
- ARHGAP17 | c.1267A>G p.T423A | Missense Mutation (SNP) | VAF 61/434 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV51505358; called by muse, mutect2, varscan2
- ARHGAP18 | c.1720G>A p.V574I | Missense Mutation (SNP) | VAF 222/1109 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.072); catalogued as rs776825955, COSV100936100; called by muse, mutect2, varscan2
- ARHGAP19 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 142/689 reads (21%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.541); catalogued as COSV100363358, COSV57393151; called by muse, mutect2, varscan2
- ARHGAP20 | c.629A>G p.Y210C | Missense Mutation (SNP) | VAF 108/863 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as rs149108692; called by muse, mutect2, varscan2
- ARHGAP21 | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 40/1212 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs1422933800; called by muse, mutect2
- ARHGAP22 | c.2078G>A p.G693D | Missense Mutation (SNP) | VAF 126/594 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.441); catalogued as COSV50943880; called by muse, varscan2
- ARHGAP22 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 102/524 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1309338429, COSV50942192; called by muse, varscan2
- ARHGAP22 | c.1150G>A p.G384S | Missense Mutation (SNP) | VAF 68/314 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs956332153, COSV50941992; called by muse, varscan2
- ARHGAP23 | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 88/519 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs1351553510; called by muse, mutect2, varscan2
- ARHGAP23 | c.2323G>A p.V775M | Missense Mutation (SNP) | VAF 62/320 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1300515552; called by muse, mutect2, varscan2
- ARHGAP23 | c.2705C>T p.A902V | Missense Mutation (SNP) | VAF 84/438 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as rs769024961; called by muse, mutect2, varscan2
- ARHGAP23 | c.2797C>T p.R933* | Nonsense Mutation (SNP) | VAF 129/648 reads (20%) | catalogued as rs1400874115; called by muse, mutect2, varscan2
- ARHGAP27 | c.1540C>T p.R514W (on ENST00000428638 / NM_001282290.1; = p.R173W on NM_199282.3) | Missense Mutation (SNP) | VAF 102/634 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772507085, COSV100976600; called by muse, mutect2, varscan2
- ARHGAP28 | c.803C>T p.A268V (on ENST00000383472 / NM_001366230.1; = p.A109V on NM_001010000.3) | Missense Mutation (SNP) | VAF 184/933 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs148484875; called by muse, mutect2, varscan2
- ARHGAP31 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 175/892 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.13); catalogued as rs1289446661; called by muse, mutect2, varscan2
- ARHGAP31 | c.3695G>A p.S1232N | Missense Mutation (SNP) | VAF 73/683 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1247087223; called by muse, mutect2, varscan2
- ARHGAP32 | c.4735A>G p.T1579A (on ENST00000310343 / NM_001378025.1; = p.T1230A on NM_014715.4) | Missense Mutation (SNP) | VAF 54/952 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs1343423601; called by muse, mutect2
- ARHGAP32 | c.1204G>A p.V402M (on ENST00000310343 / NM_001378025.1; = p.V53M on NM_014715.4) | Missense Mutation (SNP) | VAF 154/1034 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1249803580; called by muse, varscan2
- ARHGAP32 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 165/966 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs867489690, COSV59846718, COSV59848604; called by muse, mutect2, varscan2
- ARHGAP33 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 49/233 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs1412224236; called by muse, mutect2, varscan2
- ARHGAP33 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 134/534 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1343978043, COSV99137842; called by muse, mutect2, varscan2
- ARHGAP33 | c.3089C>T p.A1030V | Missense Mutation (SNP) | VAF 82/382 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.093); catalogued as rs749494760; called by muse, varscan2
- ARHGAP35 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 155/618 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1188818779; called by muse, varscan2
- ARHGAP35 | c.4253C>T p.T1418M | Missense Mutation (SNP) | VAF 30/590 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.422); catalogued as COSV101351060; called by muse, mutect2
- ARHGAP36 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 140/752 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.313); catalogued as rs759849724, COSV52268022, COSV99357196; called by muse, varscan2
- ARHGAP36 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 82/755 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV52263732, COSV99357592; called by muse, varscan2
- ARHGAP39 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 83/511 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs138981423, COSV104372895; called by muse, mutect2, varscan2
- ARHGAP4 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 78/594 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs1457829264, COSV63135216; called by muse, varscan2
- ARHGAP40 | c.1787G>A p.R596H | Missense Mutation (SNP) | VAF 117/865 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); catalogued as rs758427564, COSV54805212; called by muse, mutect2, varscan2
- ARHGAP5 | c.4097G>A p.R1366H (on ENST00000345122 / NM_001030055.2; = p.R1365H on NM_001173.3) | Missense Mutation (SNP) | VAF 74/501 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs148897080; called by muse, mutect2, varscan2
- ARHGAP6 | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 60/1258 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV100272824; called by muse, mutect2
- ARHGDIG | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 50/288 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs537147515; called by muse, mutect2, varscan2
- ARHGEF1 | c.1964C>T p.T655M | Missense Mutation (SNP) | VAF 61/393 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs201743928; called by muse, mutect2, varscan2
- ARHGEF10L | c.3274G>A p.V1092M | Missense Mutation (SNP) | VAF 71/561 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1165851186; called by muse, varscan2
- ARHGEF10L | c.3746A>G p.N1249S | Missense Mutation (SNP) | VAF 69/516 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1430069860; called by muse, mutect2, varscan2
- ARHGEF11 | c.659A>G p.D220G | Missense Mutation (SNP) | VAF 70/748 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs774152753, COSV63814292; called by muse, mutect2
- ARHGEF16 | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 73/361 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1171575959, COSV65682488; called by muse, mutect2, varscan2
- ARHGEF17 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 98/744 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.161); catalogued as rs1439459860, COSV55229061, COSV99734802; called by muse, varscan2
- ARHGEF17 | c.3644G>A p.R1215H | Missense Mutation (SNP) | VAF 168/858 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs762157933; called by mutect2, varscan2
- ARHGEF17 | c.4157C>T p.T1386I | Missense Mutation (SNP) | VAF 135/726 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); catalogued as rs1790069; called by muse, mutect2, varscan2
- ARHGEF17 | c.4685G>A p.R1562H | Missense Mutation (SNP) | VAF 115/622 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs970897906; called by muse, varscan2
- ARHGEF17 | c.5714G>T p.R1905M | Missense Mutation (SNP) | VAF 37/854 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV55231428; called by muse, mutect2
- ARHGEF18 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 92/413 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); catalogued as rs546993799, COSV60469771; called by muse, mutect2, varscan2
- ARHGEF18 | c.1600G>A p.A534T (on ENST00000359920 / NM_001130955.2; = p.A430T on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/470 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374950645; called by muse, mutect2, varscan2
- ARHGEF19 | c.1999G>A p.V667M | Missense Mutation (SNP) | VAF 106/554 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs746745880; called by muse, varscan2
- ARHGEF2 | c.1807G>A p.A603T (on ENST00000361247 / NM_001162383.2; = p.A575T on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/400 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs1160070713, COSV58115429; called by muse, mutect2, varscan2
- ARHGEF25 | c.12dup p.H5Afs*29 | Frame Shift Ins (INS) | VAF 58/260 reads (22%) | catalogued as rs747120740; called by mutect2, varscan2
- ARHGEF26 | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 165/863 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs765346404; called by muse, varscan2
- ARHGEF26 | c.2107G>A p.V703I | Missense Mutation (SNP) | VAF 136/1233 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs571135932, COSV62852509; called by muse, mutect2, varscan2
- ARHGEF26 | c.2588G>A p.R863H | Missense Mutation (SNP) | VAF 117/761 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1324480739, COSV62850712; called by muse, mutect2, varscan2
- ARHGEF28 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 111/828 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs750498517; called by muse, varscan2
- ARHGEF28 | c.2098A>G p.T700A | Missense Mutation (SNP) | VAF 147/1197 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.186); catalogued as rs769777736; called by muse, mutect2, varscan2
- ARHGEF28 | c.4535G>A p.R1512H | Missense Mutation (SNP) | VAF 65/421 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1370755407; called by muse, mutect2, varscan2
- ARHGEF35 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 33/411 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs758435535; called by muse, mutect2, varscan2
- ARHGEF38 | c.1041G>T p.K347N | Missense Mutation (SNP) | VAF 82/685 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs994104294; called by muse, mutect2, varscan2
- ARHGEF38 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 197/1135 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752087237; called by muse, mutect2, varscan2
- ARHGEF40 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 168/607 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs377294798; called by muse, mutect2, varscan2
- ARHGEF40 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 120/513 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.138); catalogued as rs1429663864; called by muse, mutect2, varscan2
- ARHGEF40 | c.3172G>A p.V1058M | Missense Mutation (SNP) | VAF 80/400 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as rs1254035455; called by muse, varscan2
- ARHGEF5 | c.3620G>A p.R1207Q | Missense Mutation (SNP) | VAF 166/1559 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.313); catalogued as rs755202652, COSV50215133; called by muse, varscan2
- ARHGEF6 | c.2260C>T p.R754W | Missense Mutation (SNP) | VAF 116/818 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs960928833, COSV51690166; called by muse, varscan2
- ARHGEF6 | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 146/966 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147323188; called by muse, mutect2, varscan2
- ARID1A | c.3667C>T p.R1223C | Missense Mutation (SNP) | VAF 155/818 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1227227387, COSV61371570; called by muse, mutect2, varscan2
- ARID1A | c.6788T>C p.V2263A | Missense Mutation (SNP) | VAF 143/680 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV61371302; called by muse, varscan2
- ARID1B | c.1826A>G p.H609R | Missense Mutation (SNP) | VAF 70/706 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.196); catalogued as COSV51677600; called by muse, varscan2
- ARID1B | c.5383C>T p.R1795C | Missense Mutation (SNP) | VAF 179/969 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs745372243, COSV51649487; called by muse, mutect2, varscan2
- ARID3A | c.1543G>A p.G515S | Missense Mutation (SNP) | VAF 55/333 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.49); catalogued as rs1174748444; called by muse, mutect2, varscan2
- ARID3B | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 97/523 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1326379631, COSV60558366; called by muse, mutect2, varscan2
- ARID3C | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 57/318 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1386504985; called by muse, mutect2, varscan2
- ARID4A | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 166/1097 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs770373766, COSV62162543; called by muse, varscan2
- ARIH1 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 104/544 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs753804913; called by muse, mutect2, varscan2
- ARIH2 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 121/584 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1370190130, COSV100711362; called by muse, mutect2, varscan2
- ARL1 | c.516-1G>T p.X172_splice | Splice Site (SNP) | VAF 66/498 reads (13%) | catalogued as COSV55370960; called by muse, mutect2, varscan2
- ARL13A | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 154/888 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773610188, COSV65880170; called by muse, mutect2, varscan2
- ARL13B | c.625C>T p.R209C (on ENST00000394222 / NM_001174150.2; = p.R102C on NM_144996.4) | Missense Mutation (SNP) | VAF 296/1448 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs755657838, COSV57398906; ClinVar: uncertain significance; called by muse, varscan2
- ARL4D | c.53A>G p.H18R | Missense Mutation (SNP) | VAF 100/911 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.281); catalogued as rs747203431; called by muse, varscan2
- ARL6IP4 | c.1189C>T p.R397* (on ENST00000315580 / NM_018694.3; = p.R378* on NM_016638.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 56/590 reads (9%) | catalogued as rs775426499; called by muse, mutect2, varscan2
- ARL8A | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 135/681 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99693366; called by muse, mutect2, varscan2
- ARL9 | c.481T>C p.Y161H (on ENST00000640821 / NM_001363794.2; = p.Y19H on NM_206919.2) | Missense Mutation (SNP) | VAF 100/819 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.657); catalogued as COSV63991081; called by muse, mutect2, varscan2
- ARMC2 | c.1658G>A p.R553H | Missense Mutation (SNP) | VAF 160/801 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs753812764, COSV64553660; called by muse, mutect2, varscan2
- ARMC3 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 62/1208 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs1441577844; called by muse, mutect2
- ARMC3 | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 150/743 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs750668869, COSV53065091, COSV53066211; called by muse, varscan2
- ARMC4 | c.1744-1G>T p.X582_splice | Splice Site (SNP) | VAF 89/410 reads (22%) | catalogued as COSV59456539; called by muse, mutect2, varscan2
- ARMC6 | c.1063G>A p.A355T (on ENST00000392336; = p.A330T on NM_033415.4) | Missense Mutation (SNP) | VAF 75/637 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs1386188873, COSV54183468; called by muse, mutect2, varscan2
- ARMC9 | c.1369C>T p.L457F | Missense Mutation (SNP) | VAF 163/668 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs773678881; called by muse, mutect2, varscan2
- ARMH2 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 230/1042 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs752947456; called by muse, varscan2
- ARMH2 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 209/1072 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs755176994; called by muse, varscan2
- ARMH3 | c.1397A>G p.D466G | Missense Mutation (SNP) | VAF 47/322 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV64236239; called by muse, varscan2
- ARMH3 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 186/920 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs745492483, COSV64233829; called by muse, mutect2, varscan2
- ARNTL | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 198/1083 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs756569611; called by muse, mutect2, varscan2
- ARSD | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 35/245 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.322); catalogued as rs759669373, COSV99472176; called by muse, mutect2, varscan2
- ARSL | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 126/684 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1054544689, COSV101140334; called by muse, mutect2, varscan2
- ART4 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 72/1583 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.329); catalogued as COSV99966860; called by muse, mutect2
- ART5 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); catalogued as COSV100731564; called by muse, varscan2
- ARVCF | c.2857G>A p.A953T | Missense Mutation (SNP) | VAF 67/547 reads (12%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs919196923; called by muse, mutect2, varscan2
- ARVCF | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 72/348 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs904916324; called by muse, mutect2, varscan2
- ARX | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 104/756 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66875685; called by muse, varscan2
- AS3MT | c.285del p.G96Dfs*3 | Frame Shift Del (DEL) | VAF 99/754 reads (13%) | catalogued as COSV54917995; called by mutect2, pindel, varscan2
- ASAP2 | c.1303G>A p.V435I | Missense Mutation (SNP) | VAF 87/651 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs763213826, COSV55635210; called by muse, mutect2, varscan2
- ASAP2 | c.1933G>A p.A645T | Missense Mutation (SNP) | VAF 116/519 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs1022357500; called by muse, mutect2, varscan2
- ASAP3 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 97/493 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs773929984, COSV60874332; called by muse, mutect2, varscan2
- ASB2 | c.668G>A p.G223D | Missense Mutation (SNP) | VAF 28/596 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as COSV60113317; called by muse, mutect2
- ASB4 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 177/1026 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1177685446; called by muse, mutect2, varscan2
- ASB6 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 189/892 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs774218305, COSV99475614; called by muse, mutect2, varscan2
- ASCC3 | c.5065C>T p.R1689C | Missense Mutation (SNP) | VAF 113/1044 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs527410635, COSV64975373; called by muse, mutect2, varscan2
- ASCC3 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 86/866 reads (10%) | catalogued as rs747266498; called by muse, mutect2
- ASCL3 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 109/590 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748424739, COSV57941056; called by muse, mutect2, varscan2
- ASIC1 | c.529del p.E177Rfs*31 | Frame Shift Del (DEL) | VAF 91/792 reads (11%) | catalogued as COSV57319909; called by mutect2, pindel, varscan2
- ASIC1 | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 64/538 reads (12%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV99948157; called by muse, mutect2, varscan2
- ASIC2 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 123/740 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs148985870; called by muse, mutect2, varscan2
- ASIC4 | c.656G>A p.G219D | Missense Mutation (SNP) | VAF 34/844 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1040613522; called by muse, mutect2
- ASMT | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 29/648 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.02); catalogued as rs1219872516; called by muse, mutect2
- ASMTL | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 82/516 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.147); catalogued as rs752524232; called by muse, varscan2
- ASNS | c.1004A>G p.D335G | Missense Mutation (SNP) | VAF 124/1644 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51556601; called by muse, mutect2
- ASNSD1 | c.770G>A p.C257Y | Missense Mutation (SNP) | VAF 254/1330 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771517751; called by muse, mutect2, varscan2
- ASPA | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 110/822 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.02); catalogued as rs777440893, COSV53980706; called by muse, mutect2, varscan2
- ASPG | c.880G>A p.V294I | Missense Mutation (SNP) | VAF 114/417 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as rs373529574; called by muse, mutect2, varscan2
- ASPH | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 116/691 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749737562, COSV65248152; called by muse, mutect2, varscan2
- ASPHD2 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 111/546 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53218923; called by muse, mutect2, varscan2
- ASPM | c.8985A>G p.T2995= | Splice Region (SNP) | VAF 145/912 reads (16%) | catalogued as rs1479711184; called by muse, mutect2, varscan2
- ASPM | c.7883C>T p.A2628V | Missense Mutation (SNP) | VAF 318/1777 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as rs61819076; called by muse, mutect2, varscan2
- ASPRV1 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 131/777 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57227903; called by muse, mutect2, varscan2
- ASPSCR1 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 63/384 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs373848028; called by muse, mutect2, varscan2
- ASS1 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 51/275 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as rs376371866, CM034721; called by muse, mutect2, varscan2
- ASTN1 | c.2471C>T p.A824V | Missense Mutation (SNP) | VAF 154/909 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV56077053; called by muse, mutect2, varscan2
- ASTN2 | c.1590C>T p.T530= (on ENST00000313400 / NM_001365069.1; = p.T479= on NM_014010.5) | Splice Region (SNP) | VAF 137/777 reads (18%) | catalogued as rs761405388, COSV57769233, COSV57772604; called by muse, mutect2, varscan2
- ASTN2 | c.1265G>A p.R422H (on ENST00000313400 / NM_001365069.1; = p.R371H on NM_014010.5) | Missense Mutation (SNP) | VAF 139/724 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs550794735; called by muse, mutect2, varscan2
- ASXL1 | c.3152G>A p.R1051H | Missense Mutation (SNP) | VAF 92/552 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.147); catalogued as rs771896604, COSV60123920; called by muse, varscan2
- ASXL2 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 229/1212 reads (19%) | catalogued as COSV55453315, COSV55459595; called by muse, mutect2, varscan2
- ASXL3 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 294/1497 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs772111853; called by muse, mutect2, varscan2
- ASXL3 | c.5243C>T p.P1748L | Missense Mutation (SNP) | VAF 49/1110 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1301566194, COSV99326802; called by muse, mutect2
- ATAD2 | c.3260C>T p.A1087V | Missense Mutation (SNP) | VAF 178/965 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs1330095007, COSV99784970; called by muse, mutect2, varscan2
- ATAD2 | c.1570C>T p.R524C | Missense Mutation (SNP) | VAF 118/742 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778430144, COSV54880549; called by muse, mutect2, varscan2
- ATAD2B | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 74/451 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as rs1318506577; called by muse, mutect2, varscan2
- ATAD3A | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 122/648 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.073); catalogued as rs746218239; called by muse, varscan2
- ATAD3A | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 142/598 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs548644017, COSV59234242; called by muse, mutect2, varscan2
- ATE1 | c.1464G>T p.Q488H | Missense Mutation (SNP) | VAF 38/1052 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV56436201; called by muse, mutect2
- ATF5 | c.787T>C p.Y263H | Missense Mutation (SNP) | VAF 54/293 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs995769211; called by muse, mutect2, varscan2
- ATF7 | c.1475C>T p.A492V (on ENST00000548446 / NM_001366555.2; = p.A481V on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/426 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as rs369186071; called by muse, mutect2, varscan2
- ATG10 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 203/1323 reads (15%) | catalogued as rs539000327, COSV56430150; called by muse, mutect2, varscan2
- ATG16L1 | c.1262C>T p.A421V (on ENST00000392017 / NM_030803.7; = p.A402V on NM_017974.4) | Missense Mutation (SNP) | VAF 105/650 reads (16%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.756); catalogued as rs751543614, COSV61465941; called by muse, mutect2, varscan2
- ATG2A | c.5389G>A p.A1797T | Missense Mutation (SNP) | VAF 95/542 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200828659; called by muse, mutect2, varscan2
- ATG2B | c.583A>G p.T195A | Missense Mutation (SNP) | VAF 43/348 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs767916667; called by muse, mutect2, varscan2
- ATG4D | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 57/400 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs769398498, COSV100470267; called by muse, mutect2, varscan2
- ATL1 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 206/1116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1459900918; called by muse, varscan2
- ATL3 | c.404A>C p.K135T | Missense Mutation (SNP) | VAF 63/352 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs758581745; called by muse, mutect2, varscan2
- ATM | c.319T>C p.C107R | Missense Mutation (SNP) | VAF 134/1026 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.352); catalogued as rs864622508, COSV53747711; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATM | c.640T>C p.S214P | Missense Mutation (SNP) | VAF 159/777 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs747053710, CD961792, COSV53739773, COSV53739922; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10A | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 111/620 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as rs751938420, COSV63517024; called by muse, mutect2, varscan2
- ATP10B | c.982T>C p.C328R | Missense Mutation (SNP) | VAF 78/791 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1223854633; called by muse, mutect2
- ATP11A | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 94/572 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1417105477, COSV52107059; called by muse, mutect2, varscan2
- ATP11B | c.377T>C p.V126A | Missense Mutation (SNP) | VAF 70/1372 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60028367; called by muse, mutect2
- ATP11C | c.1993G>A p.A665T | Missense Mutation (SNP) | VAF 171/1469 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV59565254; called by muse, mutect2, varscan2
- ATP12A | c.1985G>A p.R662H | Missense Mutation (SNP) | VAF 89/634 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs370861260; called by muse, varscan2
- ATP13A1 | c.2611G>A p.A871T | Missense Mutation (SNP) | VAF 66/480 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1026495705; called by muse, varscan2
- ATP13A1 | c.2100+5G>A | Splice Region (SNP) | VAF 56/372 reads (15%) | catalogued as rs185572197; called by muse, varscan2
- ATP13A2 | c.2270C>T p.A757V | Missense Mutation (SNP) | VAF 86/483 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1208175914, COSV58700970; called by muse, mutect2, varscan2
- ATP13A2 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 42/332 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs746292302, COSV58704042; called by muse, mutect2, varscan2
- ATP13A4 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 181/958 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.077); catalogued as rs777297473, COSV55075375; called by muse, mutect2, varscan2
- ATP1A1 | c.1607A>G p.D536G | Missense Mutation (SNP) | VAF 175/887 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as rs941562505; called by muse, mutect2, varscan2
- ATP1A2 | c.1498C>A p.H500N | Missense Mutation (SNP) | VAF 117/584 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.951); catalogued as COSV63402301; called by muse, mutect2, varscan2
- ATP2A1 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 202/969 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs908803462, COSV63920560; called by muse, mutect2, varscan2
- ATP2A3 | c.1999C>T p.R667C | Missense Mutation (SNP) | VAF 51/337 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.923); catalogued as rs1370140549; called by muse, mutect2, varscan2
- ATP2B2 | c.3361C>T p.R1121* (on ENST00000352432; = p.R1087* on NM_001683.5) | Nonsense Mutation (SNP) | VAF 36/727 reads (5%) | catalogued as COSV100659755, COSV100660044; called by muse, mutect2
- ATP2B2 | c.2323C>T p.R775W (on ENST00000352432; = p.R741W on NM_001683.5) | Missense Mutation (SNP) | VAF 108/568 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59503450; called by muse, mutect2, varscan2
- ATP2B3 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 135/752 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.048); catalogued as rs1557006336, COSV54858661; called by muse, mutect2, varscan2
- ATP2B3 | c.1181C>T p.T394M | Missense Mutation (SNP) | VAF 139/717 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs924902616, COSV54842708; called by muse, mutect2, varscan2
- ATP4A | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 75/612 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.553); catalogued as rs904563816, COSV52871892; called by muse, varscan2
- ATP4A | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 60/290 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99382601; called by muse, mutect2, varscan2
- ATP4A | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 87/418 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.141); catalogued as rs750910096, COSV52869298; called by muse, mutect2, varscan2
- ATP6AP2 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 54/1428 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs1158279990; called by muse, mutect2
- ATP6V0B | c.591G>T p.Q197H | Missense Mutation (SNP) | VAF 110/739 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV52542592; called by muse, varscan2
- ATP6V0D1 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 121/665 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52098584; called by muse, mutect2, varscan2
- ATP6V0E2 | c.133G>A p.A45T (on ENST00000425642; = p.A94T on NM_145230.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/522 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); catalogued as rs762511980, COSV70416545; called by muse, mutect2
- ATP6V1F | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 159/658 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.05); catalogued as rs11547835; called by muse, mutect2, varscan2
- ATP6V1FNB | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 119/688 reads (17%) | catalogued as rs932483328; called by muse, mutect2, varscan2
- ATP6V1H | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 119/788 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs200733079; called by muse, mutect2, varscan2
- ATP7A | c.4415G>A p.R1472H | Missense Mutation (SNP) | VAF 38/960 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.231); catalogued as rs1204475767, COSV100431773; called by muse, mutect2
- ATP7B | c.4231C>T p.R1411W | Missense Mutation (SNP) | VAF 54/435 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs559705781, COSV54441307; called by muse, varscan2
- ATP7B | c.4039G>A p.G1347S | Missense Mutation (SNP) | VAF 92/469 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587783318, CM141676, COSV99666422; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ATP7B | c.3577G>A p.A1193T | Missense Mutation (SNP) | VAF 90/513 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs769531525, CM061647, COSV54437118; called by muse, mutect2, varscan2
- ATP9A | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 119/538 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1448351539, COSV58768944; called by muse, mutect2, varscan2
- ATP9B | c.1420A>G p.T474A | Missense Mutation (SNP) | VAF 60/1146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56950563; called by muse, mutect2
- ATP9B | c.3403C>T p.R1135C | Missense Mutation (SNP) | VAF 42/318 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs768778637, COSV56947903; called by muse, mutect2, varscan2
- ATR | c.7623G>C p.R2541S | Missense Mutation (SNP) | VAF 245/1356 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV63390660; called by muse, mutect2, varscan2
- ATR | c.2878C>T p.R960* | Nonsense Mutation (SNP) | VAF 202/1125 reads (18%) | catalogued as COSV100638505; called by muse, varscan2
- ATRNL1 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 74/479 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs782160407; called by muse, mutect2, varscan2
- ATRX | c.4280G>A p.R1427H | Missense Mutation (SNP) | VAF 298/902 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs781849044, COSV64876059; called by muse, mutect2, varscan2
- ATRX | c.2841G>T p.K947N | Missense Mutation (SNP) | VAF 188/1573 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV64875965; called by muse, mutect2, varscan2
- ATRX | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 230/1388 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.278); catalogued as rs374958282, COSV64879760; ClinVar: likely benign; called by muse, varscan2
- ATXN1L | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 32/674 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1223386036; called by muse, mutect2
- ATXN1L | c.1882G>A p.A628T | Missense Mutation (SNP) | VAF 61/430 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV99077041; called by muse, varscan2
- ATXN1L | c.1970G>A p.S657N | Missense Mutation (SNP) | VAF 73/416 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs1265430087, COSV101449102; called by muse, varscan2
- ATXN7 | c.1262C>T p.T421M | Missense Mutation (SNP) | VAF 187/868 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs1157063173, COSV55756823; called by muse, mutect2, varscan2
- AURKB | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 92/478 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs777705809, COSV60245363; called by muse, varscan2
- AUTS2 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 293/1214 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.811); catalogued as rs772360830; called by muse, mutect2, varscan2
- AVIL | c.980T>C p.V327A | Missense Mutation (SNP) | VAF 99/760 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs374677661; called by muse, mutect2, varscan2
- AVIL | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 118/705 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs200603028; called by muse, mutect2, varscan2
- AVPR1B | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 87/394 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.849); catalogued as rs782107041; called by muse, mutect2, varscan2
- AVPR1B | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 99/632 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs782224020; called by muse, mutect2, varscan2
- AXIN1 | c.2234C>T p.A745V | Missense Mutation (SNP) | VAF 117/530 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs371459615; called by muse, mutect2, varscan2
- AXL | c.1378G>A p.A460T (on ENST00000301178 / NM_021913.5; = p.A451T on NM_001699.6) | Missense Mutation (SNP) | VAF 143/657 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.104); catalogued as COSV56576188; called by muse, mutect2, varscan2
- B3GALT1 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 142/900 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as rs776638733, COSV59908307; called by muse, mutect2, varscan2
- B3GLCT | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 126/710 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs139373775; called by muse, varscan2
- B3GNT7 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 84/602 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as rs764926605; called by muse, mutect2, varscan2
25,296 further variants in this file (15,267 protein-altering or splice-affecting, 5,579 silent, 4,450 other) are not listed here.
